Somatic mutation profile of tumor specimen TCGA-05-4410-01A (aliquot TCGA-05-4410-01A-21D-1855-08) from TCGA case TCGA-05-4410, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.7 years (22,888 days).
Specimen TCGA-05-4410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1146eae8-cf57-410f-9637-7e404ebcc274.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4410-10A (Blood Derived Normal), aliquot TCGA-05-4410-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3050678f-ea4a-419a-9553-ade8d2411e88

The open-access MAF lists 1,156 somatic variants for this specimen: 871 protein-altering or splice-affecting, 256 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 761, Silent 256, Nonsense Mutation 51, Splice Site 27, Frame Shift Del 19, RNA 12, Intron 9, Frame Shift Ins 4, 5'UTR 3, Splice Region 2, 3'Flank 2, Translation Start Site 2.

Variants (750 of 1,156; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 32/123 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54748170; called by muse, mutect2, varscan2
- TP53 | c.842A>T p.D281V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs587781525, CM004343, CM056068, CM114008, COSV52694391, COSV52729448, COSV52815868; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.6334T>A p.S2112T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV70036064; called by muse, mutect2, varscan2
- ABCA2 | c.5945A>T p.Y1982F (on ENST00000614293; = p.Y1952F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.747); catalogued as COSV55803940; called by muse, mutect2, varscan2
- ABCA6 | c.2336C>G p.S779* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV52638638; called by muse, mutect2
- ABCB5 | c.1536+1G>T p.X512_splice (on ENST00000404938 / NM_001163941.2; = p.X67_splice on NM_178559.6) | Splice Site (SNP) | VAF 26/84 reads (31%) | catalogued as COSV51715027; called by muse, varscan2
- ABCC1 | c.1801A>G p.M601V | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV60689864; called by muse, mutect2
- ABCC9 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 32/368 reads (9%) | catalogued as COSV53978920, COSV99684085; called by muse, mutect2
- ABCF3 | c.1149C>A p.D383E | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV53053602; called by mutect2, varscan2
- ACKR3 | c.218A>T p.K73M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV56022710; called by muse, mutect2, varscan2
- ACSM2B | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV61658959; called by muse, mutect2, varscan2
- ACTRT2 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65759859; called by muse, mutect2, varscan2
- ACVR1B | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99231465; called by muse, mutect2, varscan2
- ADAM12 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV64110452; called by muse, mutect2, varscan2
- ADAM19 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs868131208, COSV57434587; called by muse, mutect2
- ADAMTS1 | c.2051G>T p.S684I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV53171798; called by muse, mutect2, varscan2
- ADAMTS12 | c.1147G>T p.G383* | Nonsense Mutation (SNP) | VAF 40/192 reads (21%) | catalogued as COSV61257084; called by muse, varscan2
- ADAMTS5 | c.933C>G p.I311M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53181864; called by muse, mutect2, varscan2
- ADCY1 | c.3276G>T p.M1092I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52038622; called by muse, mutect2, varscan2
- ADGRG4 | c.8741G>T p.C2914F | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as COSV54961928, COSV99795616; called by muse, mutect2, varscan2
- ADGRL2 | c.2431G>T p.D811Y (on ENST00000370717 / NM_001366005.1; = p.D798Y on NM_012302.4) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs1161596453, COSV54677478; called by muse, mutect2, varscan2
- ADGRL3 | c.1436C>T p.P479L (on ENST00000506720 / NM_001322402.2; = p.P411L on NM_015236.6) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs369987771, COSV101547133; called by mutect2, varscan2
- ADH1C | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV72463558; called by muse, mutect2, varscan2
- ADH6 | c.262+2T>C p.X88_splice | Splice Site (SNP) | VAF 18/116 reads (16%) | catalogued as rs191193532, COSV52956986; called by muse, mutect2, varscan2
- ADNP2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.794); catalogued as COSV51540824; called by muse, mutect2, varscan2
- AKAP9 | c.5128G>A p.E1710K | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV62349503; called by muse, mutect2
- AL441992.2 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56915422; called by muse, mutect2
- ALK | c.3305C>T p.T1102I | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV66579645; called by muse, mutect2, varscan2
- AMELX | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.403); catalogued as COSV61631766; called by muse, mutect2, varscan2
- AMER3 | c.1723A>T p.T575S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58468371; called by muse, varscan2
- AMY1B | c.992G>A p.W331* | Nonsense Mutation (SNP) | VAF 63/340 reads (19%) | catalogued as COSV100375561; called by muse, mutect2, varscan2
- ANK1 | c.4522C>A p.P1508T | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV55887984; called by muse, mutect2, varscan2
- ANK1 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759359556, COSV55883723; called by muse, mutect2
- ANK2 | c.7520C>G p.S2507C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as COSV52175002; called by muse, mutect2, varscan2
- ANKRD17 | c.6650C>T p.S2217F | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV58224228; called by muse, mutect2
- ANKRD30A | c.3898C>A p.H1300N (on ENST00000611781; = p.H1244N on NM_052997.2) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs199841724; called by muse, mutect2, varscan2
- ANKRD35 | c.515T>A p.L172Q | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62910988, COSV62911019; called by muse, mutect2, varscan2
- ANKRD45 | c.644C>G p.T215R | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV60961890; called by muse, mutect2
- ANLN | c.728G>C p.G243A | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV56073858; called by muse, mutect2, varscan2
- ANO4 | c.2401T>A p.Y801N (on ENST00000392977 / NM_001286615.2; = p.Y766N on NM_178826.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54604803; called by muse, mutect2, varscan2
- AP1G1 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55492609; called by muse, mutect2, varscan2
- AP5S1 | c.296G>T p.R99L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV55693595, COSV55693726; called by muse, mutect2, varscan2
- APLNR | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951424; called by muse, mutect2, varscan2
- APOB | c.2503G>C p.A835P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.798); catalogued as COSV51944145; called by muse, mutect2
- APOBEC3B | c.658G>T p.V220L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV59841665; called by muse, mutect2, varscan2
- APOC3 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1435306047, COSV52636175; called by muse, mutect2
- ARHGAP21 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); catalogued as COSV57608844; called by muse, mutect2
- ARHGAP36 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV52269343; called by muse, mutect2, varscan2
- ARL13B | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV57399939; called by muse, mutect2
- ARMC2 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52900960; called by muse, mutect2, varscan2
- ARPP21 | c.148A>C p.N50H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV51802806; called by muse, mutect2, varscan2
- ASAP1 | c.33T>A p.F11L | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.827); catalogued as COSV63051815; called by muse, mutect2, varscan2
- ASB4 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.088); catalogued as COSV99987152; called by muse, mutect2, varscan2
- ATP13A5 | c.2395G>T p.G799W | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60872048; called by muse, mutect2, varscan2
- ATP2A1 | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV63921694; called by muse, mutect2
- ATP2C1 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV60759393; called by muse, mutect2, varscan2
- AURKC | c.391G>A p.E131K (on ENST00000302804 / NM_001015878.2; = p.E97K on NM_003160.3) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV100248840; called by muse, mutect2
- AVPR1B | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100899366; called by muse, mutect2, varscan2
- AXDND1 | c.301T>C p.W101R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773761120, COSV62645212, COSV62648726; called by mutect2, varscan2
- BARHL2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV64981658; called by muse, mutect2, varscan2
- BCKDHB | c.532G>T p.G178* | Nonsense Mutation (SNP) | VAF 56/156 reads (36%) | catalogued as COSV100243543; called by muse, mutect2, varscan2
- BCO2 | c.1269G>T p.E423D | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV63064197; called by muse, mutect2, varscan2
- BCS1L | c.890-1G>A p.X297_splice | Splice Site (SNP) | VAF 17/210 reads (8%) | catalogued as COSV99828972; called by muse, mutect2
- BHLHE40 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV56576000; called by muse, mutect2, varscan2
- BICC1 | c.2600G>A p.C867Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs141599424; called by muse, mutect2, varscan2
- BID | c.161G>A p.G54D (on ENST00000317361 / NM_197966.2; = p.G8D on NM_001196.4) | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1196785035, COSV100433785; called by muse, mutect2, varscan2
- BIN1 | c.1566G>T p.M522I (on ENST00000316724 / NM_001320642.1; = p.M383I on NM_004305.4) | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99387940; called by muse, mutect2, varscan2
- BMP4 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV55416620; called by muse, mutect2, varscan2
- BMPER | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV51825717; called by muse, mutect2, varscan2
- BPTF | c.8860G>C p.E2954Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as COSV58841842; called by muse, mutect2
- BRINP2 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV100838063; called by muse, mutect2, varscan2
- BRINP2 | c.2120C>G p.P707R | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100838064; called by muse, mutect2, varscan2
- BRINP3 | c.2042G>T p.R681L | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV66519124; called by muse, mutect2, varscan2
- BRINP3 | c.1558C>A p.R520S | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV66532324, COSV66543305; called by muse, mutect2
- BRINP3 | c.314C>G p.P105R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66532334; called by muse, mutect2, varscan2
- BTD | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57729837; called by muse, mutect2
- C10orf71 | c.986C>A p.A329D | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV60510212; called by muse, mutect2, varscan2
- C10orf88 | c.859A>T p.N287Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV64404190; called by muse, mutect2, varscan2
- C16orf78 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV54557366, COSV54558160; called by muse, mutect2, varscan2
- C5AR2 | c.793C>A p.L265I | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.377); catalogued as COSV99953743, COSV99953875; called by muse, mutect2, varscan2
- C5orf58 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50456733; called by muse, mutect2
- C8orf37 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs369471163; called by muse, mutect2
- CAB39L | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1470284530, COSV61715843; called by muse, mutect2, varscan2
- CABYR | c.239T>A p.L80* | Nonsense Mutation (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100510042; called by muse, mutect2, varscan2
- CACNA1G | c.4504G>T p.D1502Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61722680, COSV61732558; called by muse, mutect2, varscan2
- CACNB2 | c.213+1G>T p.X71_splice (on ENST00000324631 / NM_201596.3; = p.X43_splice on NM_201571.4) | Splice Site (SNP) | VAF 32/156 reads (21%) | catalogued as rs754812063, COSV56636403; called by muse, mutect2, varscan2
- CACNG6 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.379); catalogued as COSV53167402; called by muse, mutect2, varscan2
- CADPS | c.2837A>T p.D946V | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV51891622; called by muse, mutect2
- CADPS | c.2835G>T p.W945C | Missense Mutation (SNP) | VAF 108/400 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV51891635, COSV51897528; called by muse, mutect2
- CALCRL | c.11A>G p.K4R | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV66476154; called by muse, mutect2
- CALD1 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100724214, COSV62646234; called by muse, mutect2, varscan2
- CAP2 | c.46A>G p.S16G | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57734601; called by muse, mutect2, varscan2
- CASQ1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63624364; called by muse, mutect2, varscan2
- CBFA2T2 | c.593A>T p.Q198L | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100656311; called by muse, mutect2
- CBX3 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100522930; called by muse, mutect2, varscan2
- CCDC136 | c.1145A>T p.Q382L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52802269; called by muse, mutect2, varscan2
- CCDC15 | c.1812G>T p.Q604H | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.192); catalogued as COSV100776968; called by muse, mutect2, varscan2
- CCDC178 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.201); catalogued as rs548517073, COSV55784938; called by muse, mutect2, varscan2
- CCDC191 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV55674258; called by muse, mutect2
- CCDC50 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.188); catalogued as COSV66668912; called by muse, mutect2, varscan2
- CCDC63 | c.1110G>C p.L370F | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.178); catalogued as COSV57529560; called by muse, mutect2, varscan2
- CCDC80 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV52818561; called by muse, mutect2, varscan2
- CCKAR | c.811C>A p.L271M | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55162652; called by muse, mutect2, varscan2
- CCNA1 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.555); catalogued as COSV55222845; called by mutect2, varscan2
- CCP110 | c.1659A>T p.L553F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV66817430; called by muse, mutect2, varscan2
- CCT5 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV54724760; called by muse, mutect2
- CD180 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.096); catalogued as COSV56518984; called by muse, mutect2, varscan2
- CD1C | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 182/597 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63807005, COSV63807643; called by muse, mutect2, varscan2
- CD200R1 | c.430G>T p.G144* (on ENST00000471858 / NM_170780.3; = p.G167* on NM_138806.4) | Nonsense Mutation (SNP) | VAF 19/123 reads (15%) | catalogued as COSV55602211, COSV55604027; called by muse, mutect2, varscan2
- CD40LG | c.498A>C p.Q166H | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV65698740; called by muse, mutect2, varscan2
- CD96 | c.1297+1G>T p.X433_splice (on ENST00000283285 / NM_198196.3; = p.X417_splice on NM_005816.5) | Splice Site (SNP) | VAF 9/62 reads (15%) | catalogued as COSV51919462; called by muse, mutect2, varscan2
- CDC14A | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV60560686; called by muse, mutect2, varscan2
- CDC14A | c.1185G>C p.Q395H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100325025; called by muse, mutect2
- CDC14A | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 4/66 reads (6%) | catalogued as COSV100325032; called by muse, mutect2
- CDC42BPA | c.647G>C p.R216P | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62015794; called by muse, mutect2, varscan2
- CDH10 | c.1739G>C p.G580A | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.32); catalogued as COSV52588787; called by muse, mutect2, varscan2
- CDH10 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52588793; called by muse, mutect2, varscan2
- CDH11 | c.1870C>A p.L624I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV51769558; called by muse, mutect2, varscan2
- CDH12 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV66425478; called by muse, mutect2, varscan2
- CDH12 | c.525G>T p.V175= | Splice Region (SNP) | VAF 68/203 reads (33%) | catalogued as COSV66404472, COSV66425487; called by muse, mutect2, varscan2
- CDH18 | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56941899, COSV99935521; called by muse, mutect2, varscan2
- CDH19 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV50966382; called by muse, mutect2, varscan2
- CDH4 | c.482C>G p.A161G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV64664658; called by muse, mutect2, varscan2
- CDH8 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100181330, COSV54848603; called by muse, mutect2, varscan2
- CDK14 | c.430G>T p.G144* (on ENST00000380050 / NM_001287135.2; = p.G126* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 22/308 reads (7%) | catalogued as COSV56043685; called by muse, mutect2
- CELSR3 | c.2844G>T p.E948D | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV99373442; called by muse, mutect2, varscan2
- CELSR3 | c.2843A>T p.E948V | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99373445; called by muse, mutect2, varscan2
- CEP97 | c.435G>T p.L145F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59126062; called by muse, mutect2, varscan2
- CER1 | c.558C>A p.C186* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV101097806; called by muse, mutect2, varscan2
- CFAP52 | c.1850C>A p.P617Q | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53304916; called by muse, mutect2, varscan2
- CFAP61 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV55626303, COSV55638420; called by muse, mutect2, varscan2
- CFAP91 | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV56342840; called by muse, mutect2, varscan2
- CHD3 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.127); catalogued as COSV57877782; called by muse, mutect2, varscan2
- CHML | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59365943; called by muse, mutect2, varscan2
- CHRD | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52610295; called by muse, mutect2, varscan2
- CHST1 | c.1047del p.V350Cfs*45 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as COSV100346538, COSV100346594; called by mutect2, pindel, varscan2
- CLDN10 | c.675T>A p.N225K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100176142; called by muse, mutect2, varscan2
- CLEC3A | c.574T>C p.C192R (on ENST00000651443; = p.C183R on NM_005752.6) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55222559; called by muse, mutect2, varscan2
- CLK2 | c.1442G>T p.R481L (on ENST00000368361 / NM_001294339.2; = p.R480L on NM_003993.4) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV56946534; called by muse, mutect2, varscan2
- CMKLR1 | c.596G>T p.G199V (on ENST00000312143 / NM_001142344.2; = p.G197V on NM_004072.3) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV56436360; called by muse, mutect2, varscan2
- CMYA5 | c.5685G>T p.M1895I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs747342218, COSV71407715; called by muse, mutect2, varscan2
- CNDP1 | c.1248C>A p.H416Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV62594561; called by muse, mutect2, varscan2
- CNGA2 | c.1811T>A p.L604Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61705402; called by muse, mutect2, varscan2
- CNNM1 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs1564935129, COSV100763849, COSV63201512; called by muse, mutect2, varscan2
- CNOT4 | c.292A>T p.K98* | Nonsense Mutation (SNP) | VAF 38/144 reads (26%) | catalogued as COSV59655643; called by muse, mutect2, varscan2
- CNTNAP2 | c.1913C>T p.T638I | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV62220441; called by muse, mutect2
- CNTNAP3 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99904725; called by muse, mutect2, varscan2
- CNTNAP4 | c.154A>T p.S52C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56691150; called by muse, mutect2, varscan2
- CNTNAP4 | c.2820G>T p.M940I | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV56691202; called by muse, mutect2, varscan2
- CNTNAP5 | c.808C>A p.H270N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101443081, COSV70498010; called by muse, mutect2, varscan2
- CNTNAP5 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.674); catalogued as COSV70498013; called by muse, mutect2
- COA6 | c.198del p.W66* | Frame Shift Del (DEL) | VAF 38/163 reads (23%) | catalogued as rs752068421; called by mutect2, pindel, varscan2
- COL11A1 | c.2951G>T p.R984L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62189967; called by muse, mutect2, varscan2
- COL11A1 | c.2611-1G>C p.X871_splice | Splice Site (SNP) | VAF 4/39 reads (10%) | catalogued as COSV62189975, COSV62191057, COSV62196401; called by muse, mutect2, varscan2
- COL12A1 | c.2775G>T p.W925C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59401309; called by muse, mutect2, varscan2
- COL18A1 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV62704261; called by muse, mutect2, varscan2
- COL25A1 | c.1946C>G p.P649R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); catalogued as COSV67680296; called by muse, mutect2
- COL27A1 | c.2062G>T p.G688W | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61928738; called by muse, varscan2
- COL4A4 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV61634352; called by muse, mutect2, varscan2
- COL5A1 | c.3572C>T p.P1191L | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV65672113; called by muse, mutect2, varscan2
- COL6A3 | c.5167C>A p.L1723I | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55092157, COSV55098789; called by muse, mutect2, varscan2
- COL7A1 | c.7854C>G p.F2618L | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.023); catalogued as COSV56476865; called by muse, mutect2
- COL9A1 | c.2128G>T p.E710* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100295919, COSV57888155; called by muse, mutect2, varscan2
- COL9A2 | c.577-2A>T p.X193_splice | Splice Site (SNP) | VAF 16/58 reads (28%) | catalogued as COSV65607812; called by muse, mutect2, varscan2
- COP1 | c.834A>G p.Q278= | Splice Region (SNP) | VAF 11/37 reads (30%) | catalogued as COSV58171571; called by muse, mutect2, varscan2
- COPS5 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63474682; called by muse, mutect2, varscan2
- COQ9 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52645668, COSV52646617; called by muse, mutect2, varscan2
- CORIN | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56695295; called by muse, mutect2, varscan2
- CPE | c.497C>A p.A166E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV68581497; called by muse, mutect2, varscan2
- CPED1 | c.2801C>A p.T934K | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60007522; called by muse, mutect2, varscan2
- CPLANE1 | c.7681A>G p.T2561A | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57067171; called by muse, mutect2, varscan2
- CPLX2 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); catalogued as COSV64001415; called by muse, mutect2, varscan2
- CPPED1 | c.86G>T p.W29L | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV55499459; called by mutect2, varscan2
- CRISPLD1 | c.1244+1G>T p.X415_splice | Splice Site (SNP) | VAF 22/55 reads (40%) | catalogued as COSV51551028; called by muse, mutect2, varscan2
- CRNN | c.1219G>T p.G407W | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV55122976; called by muse, mutect2, varscan2
- CRTC3 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as rs375397418; called by muse, mutect2
- CRYBG2 | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as rs756342640; called by muse, mutect2, varscan2
- CSGALNACT2 | c.316G>T p.G106C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV65676082; called by muse, mutect2, varscan2
- CSMD2 | c.2080C>G p.P694A | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53935040, COSV53938795; called by muse, mutect2, varscan2
- CSMD3 | c.9115G>T p.G3039C (on ENST00000297405 / NM_001363185.1; = p.G2870C on NM_052900.3) | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52248094; called by muse, mutect2, varscan2
- CTAGE6 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101417845; called by mutect2, varscan2
- CTNNA2 | c.1271A>C p.H424P | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58157396, COSV58165333; called by muse, mutect2, varscan2
- CTNNA2 | c.1422G>T p.Q474H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV58165346; called by muse, mutect2, varscan2
- CTNND2 | c.1669C>G p.Q557E | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.914); catalogued as rs1360300991, COSV58890592, COSV58907203, COSV58908119; called by muse, mutect2, varscan2
- CTSF | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as COSV59747547, COSV59749714; called by muse, mutect2, varscan2
- CUBN | c.5173G>A p.G1725R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV64721605; called by muse, mutect2, varscan2
- CUL4A | c.1123G>A p.V375M (on ENST00000375440 / NM_001008895.4; = p.V275M on NM_003589.3) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs769425622, COSV100417197; called by muse, mutect2, varscan2
- CWC27 | c.558A>C p.K186N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV66887346; called by muse, mutect2
- CWF19L2 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.06); catalogued as COSV56516299; called by muse, mutect2, varscan2
- CWF19L2 | c.1364A>T p.Q455L | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV56516322; called by muse, mutect2
- CX3CR1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs1293157339, COSV64194545; called by muse, mutect2, varscan2
- CXCL9 | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.089); catalogued as COSV53579322; called by muse, mutect2, varscan2
- CXCR4 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.564); catalogued as COSV54014545; called by muse, mutect2, varscan2
- CYP4B1 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54722925, COSV54724778; called by muse, mutect2, varscan2
- CYP4F3 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV55411795; called by muse, mutect2, varscan2
- CYRIA | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.065); catalogued as COSV62866104; called by muse, mutect2
- DACH1 | c.1547T>A p.V516E (on ENST00000619232 / NM_001366712.1; = p.V464E on NM_080759.6) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.974); catalogued as COSV57510834; called by muse, mutect2, varscan2
- DACH1 | c.896del p.P299Qfs*19 | Frame Shift Del (DEL) | VAF 12/85 reads (14%) | catalogued as COSV100499529; called by mutect2, pindel, varscan2
- DCAF6 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56581773; called by muse, mutect2, varscan2
- DCC | c.3736G>T p.A1246S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV71436223; called by muse, mutect2, varscan2
- DCLRE1C | c.767G>T p.C256F (on ENST00000378278 / NM_001350965.2; = p.C141F on NM_022487.4) | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63184462; called by muse, mutect2
- DDHD1 | c.153T>G p.D51E (on ENST00000323669; = p.D282E on NM_030637.3) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.022); catalogued as COSV60360792; called by muse, mutect2
- DDIAS | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61272721; called by muse, mutect2, varscan2
- DDX53 | c.1838G>T p.R613I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60069595; called by muse, mutect2, varscan2
- DDX60L | c.3439G>A p.V1147I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV52717537; called by muse, mutect2
- DECR1 | c.948+1G>T p.X316_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as rs768371218, COSV55169551; called by muse, mutect2, varscan2
- DEFB110 | c.95G>T p.R32M | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV100953807, COSV64484690; called by muse, mutect2, varscan2
- DENND4C | c.4603G>T p.E1535* (on ENST00000434457 / NM_001330640.2; = p.E1486* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV63009286; called by muse, mutect2, varscan2
- DGKG | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as rs370992136; called by muse, mutect2, varscan2
- DIP2A | c.3703G>A p.A1235T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.027); catalogued as COSV59482387; called by muse, mutect2, varscan2
- DIP2B | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56588205; called by muse, mutect2, varscan2
- DLG2 | c.1070A>T p.K357M | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.62); catalogued as COSV54665601, COSV54681076; called by muse, mutect2, varscan2
- DLG2 | c.43-2A>G p.X15_splice | Splice Site (SNP) | VAF 19/234 reads (8%) | catalogued as COSV65854280; called by muse, mutect2
- DLGAP3 | c.1238C>A p.P413H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52395827; called by muse, mutect2, varscan2
- DMP1 | c.962G>T p.S321I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56821332; called by muse, mutect2, varscan2
- DMP1 | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56821351; called by muse, mutect2, varscan2
- DMWD | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); catalogued as COSV52180205; called by muse, mutect2, varscan2
- DNAAF3 | c.1438G>T p.A480S (on ENST00000524407 / NM_001256715.2; = p.A527S on NM_178837.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.197); catalogued as COSV61278280; called by muse, mutect2, varscan2
- DNAH11 | c.3193G>T p.D1065Y | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60967040; called by muse, mutect2, varscan2
- DNAH3 | c.3637G>A p.D1213N | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV54536134; called by muse, mutect2, varscan2
- DNAH9 | c.2354-1G>C p.X785_splice | Splice Site (SNP) | VAF 18/85 reads (21%) | catalogued as COSV52362348; called by muse, mutect2, varscan2
- DNAH9 | c.9122C>A p.P3041H | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52362361; called by muse, mutect2, varscan2
- DNAI3 | c.2228G>A p.W743* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | catalogued as COSV54004341, COSV99642006; called by muse, mutect2
- DNAI4 | c.2183G>T p.G728V | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs1399872193, COSV64030420; called by muse, mutect2, varscan2
- DNMT1 | c.3964G>C p.E1322Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as COSV61581442; called by muse, mutect2, varscan2
- DNTTIP2 | c.815G>T p.R272I | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV63284129, COSV63284356; called by muse, mutect2, varscan2
- DRD1 | c.492C>A p.H164Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101192437; called by muse, mutect2, varscan2
- DSG1 | c.985G>T p.G329* | Nonsense Mutation (SNP) | VAF 14/101 reads (14%) | catalogued as COSV57137512; called by muse, mutect2, varscan2
- DST | c.5170G>T p.V1724L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV99755407; called by muse, varscan2
- DTNA | c.2047A>T p.S683C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV52014886; called by muse, mutect2, varscan2
- DTWD1 | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99233624; called by muse, mutect2, varscan2
- DUSP28 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as COSV56037675; called by muse, mutect2, varscan2
- DYNAP | c.68G>T p.G23V (on ENST00000321600; = p.G26V on NM_001307955.1) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as COSV58666662; called by muse, mutect2, varscan2
- DYNC2H1 | c.4850A>T p.Q1617L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1332438332, COSV62100240; called by muse, mutect2
- DYNC2H1 | c.11602G>T p.A3868S | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.785); catalogued as COSV62100250; called by muse, varscan2
- DYNC2H1 | c.12243T>G p.F4081L | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as COSV62100260; called by muse, mutect2, varscan2
- DYSF | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM053212, COSV50483645; called by muse, mutect2, varscan2
- DZIP1 | c.1268A>T p.Q423L | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV61267625; called by muse, mutect2, varscan2
- DZIP1 | c.1172G>C p.R391P | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.296); catalogued as COSV61267637, COSV99051996; called by muse, mutect2, varscan2
- ECT2 | c.476A>G p.Q159R (on ENST00000392692 / NM_001349098.2; = p.Q128R on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51691378; called by muse, mutect2
- EED | c.964A>G p.K322E | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54556969; called by muse, mutect2, varscan2
- EEFSEC | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as COSV54625989, COSV54629076; called by muse, mutect2, varscan2
- EGFR | c.1131G>T p.R377S | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV51823181; called by muse, mutect2, varscan2
- EIF4G1 | c.4642G>T p.A1548S (on ENST00000346169 / NM_198241.3; = p.A1353S on NM_004953.5) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as rs1333924370, COSV100071751, COSV59992364; called by muse, mutect2
- ELMO1 | c.2101C>A p.L701M | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV60314095; called by muse, mutect2, varscan2
- ELOA2 | c.1029C>G p.D343E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV55303392; called by muse, mutect2, varscan2
- ELOVL7 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70918330; called by muse, mutect2, varscan2
- ENHO | c.211A>G p.S71G | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV99646798; called by muse, mutect2, varscan2
- ENPEP | c.1691C>A p.P564Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.406); catalogued as COSV54454099; called by muse, mutect2, varscan2
- EPG5 | c.3732C>G p.I1244M | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV56352819; called by muse, mutect2, varscan2
- EPHA3 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60715972; called by muse, mutect2
- EPHA7 | c.2668C>G p.L890V | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65187705; called by muse, mutect2, varscan2
- EPHA7 | c.2086C>A p.H696N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65183875; called by muse, mutect2, varscan2
- EPHB1 | c.793G>T p.V265L | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.169); catalogued as COSV67665974; called by muse, varscan2
- EPHB6 | c.2669G>T p.G890V | Missense Mutation (SNP) | VAF 53/376 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.778); catalogued as COSV100844452, COSV63892659; called by muse, mutect2, varscan2
- ERICH3 | c.3643G>T p.A1215S | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs780934042, COSV58612604; called by muse, mutect2, varscan2
- ERICH3 | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV58612609; called by muse, mutect2, varscan2
- EXOC2 | c.1409G>A p.W470* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as COSV57868918; called by muse, mutect2, varscan2
- EYS | c.1324A>C p.K442Q | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100676388; called by muse, mutect2
- F13B | c.1157C>G p.P386R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV66374832, COSV66375465; called by muse, mutect2
- F13B | c.943C>A p.R315S | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV66374836, COSV66374843; called by muse, mutect2, varscan2
- FAM118B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV64157420; called by muse, mutect2, varscan2
- FAM171B | c.1882C>A p.L628M | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV59006039; called by muse, mutect2, varscan2
- FAM171B | c.2191C>A p.H731N | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV59006050; called by muse, mutect2, varscan2
- FAM47C | c.2003C>A p.P668Q | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV63723919, COSV63728732, COSV63728956, COSV63730909; called by muse, mutect2, varscan2
- FAM81A | c.96G>T p.Q32H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.73); catalogued as COSV55679270; called by muse, mutect2, varscan2
- FAM83G | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV58760166; called by muse, mutect2, varscan2
- FAM83H | c.1450G>C p.A484P | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1359094958, COSV66353638, COSV66354258; called by muse, mutect2, varscan2
- FARP2 | c.1961del p.C654Lfs*26 | Frame Shift Del (DEL) | VAF 68/209 reads (33%) | catalogued as COSV99885263; called by mutect2, pindel, varscan2
- FASLG | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV60680538; called by muse, mutect2, varscan2
- FAT4 | c.10807C>T p.H3603Y | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.615); catalogued as COSV58697916; called by muse, mutect2, varscan2
- FAT4 | c.14770G>T p.G4924W | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58697937; called by muse, mutect2, varscan2
- FBN2 | c.6907C>A p.H2303N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.192); catalogued as COSV52529295; called by muse, mutect2, varscan2
- FCGR2A | c.548G>T p.G183V (on ENST00000271450 / NM_001136219.3; = p.G182V on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54839812; called by muse, mutect2, varscan2
- FGD5 | c.1341G>T p.Q447H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV53247391; called by muse, mutect2, varscan2
- FGF14 | c.744G>T p.*248Yext*17 | Nonstop Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV65950223; called by muse, mutect2, varscan2
- FGF5 | c.312C>A p.Y104* | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV56889350; called by muse, mutect2, varscan2
- FGFR1 | c.508G>T p.A170S (on ENST00000447712 / NM_023110.3; = p.A168S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100248097; called by muse, mutect2
- FIGNL1 | c.331A>T p.K111* | Nonsense Mutation (SNP) | VAF 15/136 reads (11%) | catalogued as COSV63553811; called by muse, mutect2, varscan2
- FITM1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.382); catalogued as COSV99246223; called by muse, mutect2, varscan2
- FKBP6 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52721687; called by muse, mutect2, varscan2
- FKTN | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56310861; called by muse, mutect2
- FLG2 | c.4013G>T p.R1338I | Missense Mutation (SNP) | VAF 17/395 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV66170808; called by muse, mutect2
- FLNC | c.6361+1G>T p.X2121_splice | Splice Site (SNP) | VAF 20/68 reads (29%) | catalogued as COSV57960137; called by muse, mutect2, varscan2
- FLT4 | c.1822C>T p.L608F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV56115848; called by muse, mutect2, varscan2
- FLT4 | c.1472C>A p.A491E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV56099675, COSV56115874; called by muse, mutect2, varscan2
- FMN2 | c.4549G>A p.D1517N | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60441480; called by muse, mutect2
- FNDC3A | c.3247C>T p.Q1083* (on ENST00000492622 / NM_001079673.2; = p.Q1027* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV68134132; called by muse, mutect2
- FOCAD | c.2435G>C p.G812A | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV100620370; called by muse, mutect2
- FOCAD | c.2718G>T p.Q906H | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58103902; called by muse, varscan2
- FOCAD | c.4123G>C p.G1375R | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58097224, COSV58103915; called by muse, mutect2, varscan2
- FOLH1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV57052785; called by muse, mutect2
- FOXR2 | c.905C>A p.P302Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99080877; called by muse, mutect2, varscan2
- FRAS1 | c.1145G>T p.C382F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53628509; called by muse, mutect2, varscan2
- FRS2 | c.1323G>T p.L441F | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); catalogued as COSV100165954; called by muse, mutect2, varscan2
- FSIP2 | c.16573G>T p.V5525L | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100555046; called by muse, mutect2, varscan2
- FSTL5 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV60211764; called by muse, mutect2, varscan2
- GABRB1 | c.818C>A p.A273E | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54991638; called by muse, mutect2, varscan2
- GABRQ | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as rs782675594, COSV64781125; called by muse, mutect2, varscan2
- GAD1 | c.1525G>C p.E509Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.181); catalogued as COSV64026823; called by muse, mutect2, varscan2
- GAL3ST3 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV61749401; called by muse, mutect2, varscan2
- GCDH | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as rs372429120, COSV99712747; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCNT1 | c.118T>A p.F40I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV65058209; called by muse, mutect2, varscan2
- GDA | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52995560; called by muse, mutect2, varscan2
- GIMAP8 | c.418G>T p.G140W | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV56232766; called by muse, mutect2, varscan2
- GJA8 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53787721, COSV99569344; called by muse, mutect2, varscan2
- GK | c.931G>A p.A311T (on ENST00000427190 / NM_001205019.2; = p.A305T on NM_000167.6) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66737851; called by muse, mutect2, varscan2
- GOLGB1 | c.2333G>C p.R778T | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV61468210; called by muse, mutect2, varscan2
- GPC3 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV63668102; called by muse, mutect2, varscan2
- GPC6 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as COSV65522734; called by muse, mutect2
- GPR101 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV99981397; called by muse, mutect2, varscan2
- GPR156 | c.1159A>T p.M387L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV59941354; called by muse, mutect2, varscan2
- GPR158 | c.2490G>T p.E830D | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV66276624; called by muse, mutect2, varscan2
- GPR63 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.041); catalogued as COSV100013178, COSV57742416; called by muse, mutect2, varscan2
- GPR65 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99966026; called by muse, mutect2, varscan2
- GPR83 | c.132G>T p.W44C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV54719715; called by muse, mutect2, varscan2
- GRAP2 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59996213; called by muse, mutect2, varscan2
- GRIA1 | c.1231G>T p.V411F | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53613763; called by muse, mutect2, varscan2
- GRK5 | c.126T>A p.C42* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as COSV67311924; called by muse, mutect2, varscan2
- GRM7 | c.2413A>G p.I805V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.956); catalogued as COSV63155439; called by muse, mutect2
- GRM8 | c.1618C>A p.R540S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.069); catalogued as COSV58846803; called by muse, mutect2, varscan2
- GUSB | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 12/102 reads (12%) | catalogued as COSV59222706; called by muse, mutect2, varscan2
- H2AC8 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99773218; called by muse, mutect2, varscan2
- H2BC9 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV55099863, COSV55100002; called by muse, mutect2, varscan2
- H3C7 | c.299A>T p.Y100F | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV99769093; called by muse, mutect2
- HAND2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs866374463, COSV64017975; called by muse, mutect2
- HAO1 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66492962; called by muse, mutect2, varscan2
- HAUS6 | c.1191+2T>G p.X397_splice | Splice Site (SNP) | VAF 30/94 reads (32%) | catalogued as COSV65840386; called by muse, mutect2, varscan2
- HCRTR2 | c.1085T>A p.I362N | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63797426, COSV63799635; called by muse, mutect2, varscan2
- HDC | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs777905414, COSV51070898, COSV51074991; called by muse, mutect2, varscan2
- HECW1 | c.3937G>T p.G1313* | Nonsense Mutation (SNP) | VAF 35/172 reads (20%) | catalogued as COSV67835255; called by muse, mutect2, varscan2
- HECW1 | c.4210G>C p.D1404H | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV67835264, COSV67839862; called by muse, mutect2
- HELZ2 | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64410086; called by muse, mutect2
- HFM1 | c.2402G>A p.S801N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1411733775, COSV54032670; called by muse, mutect2
- HGF | c.1228C>A p.L410I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.976); catalogued as COSV55953318; called by muse, mutect2, varscan2
- HKDC1 | c.2552A>T p.E851V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV63578259; called by muse, mutect2, varscan2
- HMGCLL1 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV51448398; called by muse, mutect2, varscan2
- HMOX1 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53340676; called by muse, mutect2, varscan2
- HNRNPDL | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 11/117 reads (9%) | catalogued as COSV55023124; called by muse, mutect2
- HNRNPH1 | c.65G>A p.C22Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV61487434; called by muse, mutect2, varscan2
- HOXC13 | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV54499414; called by muse, mutect2, varscan2
- HOXD13 | c.781+1G>T p.X261_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as CS1310806, COSV101184266; called by muse, mutect2
- HSF5 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV60418092; called by muse, mutect2
- HSPG2 | c.7356G>C p.Q2452H | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65974377; called by muse, mutect2
- HTR1A | c.629T>A p.L210H | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60501923; called by muse, mutect2, varscan2
- HTR1E | c.912G>T p.W304C | Missense Mutation (SNP) | VAF 21/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59509157; called by muse, mutect2
- HTR5A | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.135); catalogued as COSV55285207, COSV55287981; called by muse, mutect2, varscan2
- HTR5A | c.894G>T p.W298C | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55284835, COSV55285263; called by muse, varscan2
- ICA1 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV55581473; called by muse, mutect2, varscan2
- IFNA10 | c.447A>T p.R149S | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.895); catalogued as rs756811442, COSV99497468; called by muse, mutect2
- IGF2R | c.6987G>C p.K2329N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs760128656, COSV63630932; called by muse, mutect2, varscan2
- IGHV3-49 | c.308A>T p.Q103L | Missense Mutation (SNP) | VAF 85/228 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); catalogued as rs782044491; called by muse, mutect2, varscan2
- IGKV1D-43 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as rs1372891701; called by muse, mutect2
- IL4R | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50154593; called by muse, mutect2, varscan2
- IL7R | c.1082T>A p.F361Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.115); catalogued as COSV57410935; called by muse, mutect2, varscan2
- ILDR2 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54833293; called by muse, mutect2, varscan2
- ING1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as rs1240276606, COSV58167204, COSV58169293; called by muse, mutect2, varscan2
- INPP5A | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766031019, COSV61250880; called by muse, mutect2, varscan2
- INPP5A | c.1177C>T p.R393* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs201882680; called by muse, mutect2, varscan2
- INTS1 | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67178572; called by muse, mutect2
- IST1 | c.983G>T p.R328I (on ENST00000535424 / NM_001270976.1; = p.D314Y on NM_014761.4) | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV58665018; called by muse, mutect2, varscan2
- ITGAL | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as COSV63323353; called by muse, mutect2, varscan2
- ITGAX | c.2782del p.V928Lfs*50 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | catalogued as COSV99191378, COSV99191778; called by mutect2, pindel, varscan2
- ITGB3 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101457592; called by muse, mutect2, varscan2
- JUP | c.1300G>T p.G434C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60279025, COSV60279955; called by muse, mutect2, varscan2
- KANK4 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV62987921; called by muse, mutect2, varscan2
- KCNA6 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.143); catalogued as COSV54975771; called by muse, mutect2, varscan2
- KCNAB1 | c.357G>T p.E119D (on ENST00000490337 / NM_172160.3; = p.E108D on NM_003471.3) | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV100204268; called by muse, mutect2, varscan2
- KCNB2 | c.1005G>T p.L335F | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV73050527; called by muse, mutect2, varscan2
- KCNH6 | c.2956C>T p.P986S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs763774067, COSV59005611; called by muse, mutect2, varscan2
- KCNJ16 | c.147C>A p.H49Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.28); catalogued as COSV99388285; called by muse, mutect2
- KCNK9 | c.587C>A p.T196K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752611105, COSV57285276; called by muse, mutect2, varscan2
- KCNT2 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV54093542; called by muse, mutect2, varscan2
- KCTD15 | c.676C>G p.R226G | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV52291173; called by muse, mutect2, varscan2
- KHDRBS2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55465481; called by muse, mutect2, varscan2
- KIAA0513 | c.504G>T p.E168D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV50742547; called by muse, mutect2, varscan2
- KIAA1328 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.116); catalogued as COSV54459636; called by muse, mutect2, varscan2
- KIAA1614 | c.709A>T p.R237W | Missense Mutation (SNP) | VAF 90/275 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62553212; called by muse, mutect2, varscan2
- KIF1B | c.3004G>A p.V1002M (on ENST00000377086 / NM_001365952.1; = p.V956M on NM_015074.3) | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55812090; called by muse, mutect2, varscan2
- KIF2B | c.1382G>C p.S461T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV52133193; called by muse, mutect2, varscan2
- KIF6 | c.1494G>T p.M498I | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV54685833; called by muse, mutect2
- KIF7 | c.3424C>A p.L1142M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV51541503; called by muse, mutect2, varscan2
- KIR2DL4 | c.952C>A p.P318T (on ENST00000396284; = p.P244T on NM_001080770.2) | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58493509; called by muse, mutect2, varscan2
- KIR3DL1 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 128/419 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV58493521; called by muse, mutect2, varscan2
- KIRREL1 | c.1720-2A>G p.X574_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as COSV63289381; called by muse, mutect2
- KLHL32 | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100987179, COSV65113323; called by muse, mutect2, varscan2
- KLHL38 | c.402C>A p.S134R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.361); catalogued as rs773580578, COSV58088328; called by muse, mutect2, varscan2
- KLHL4 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as rs776535078, COSV64144614, COSV64145221; called by muse, mutect2, varscan2
- KRT74 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59772543; called by muse, mutect2, varscan2
- KRTAP19-6 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs146590456; called by muse, mutect2
- KRTAP21-2 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.026); catalogued as rs1203154675, COSV100441181; called by muse, mutect2
- KRTAP21-2 | c.204T>G p.C68W | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV100441184; called by muse, mutect2
- KRTAP9-8 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as COSV99565821; called by muse, mutect2, varscan2
- L1CAM | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV62829064; called by muse, varscan2
- L1TD1 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as COSV63133762; called by muse, mutect2, varscan2
- LAMA2 | c.820-2A>T p.X274_splice | Splice Site (SNP) | VAF 25/97 reads (26%) | catalogued as COSV101370426; called by muse, mutect2, varscan2
- LAMA4 | c.1217G>T p.G406V (on ENST00000230538 / NM_001105206.3; = p.G399V on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV57901408; called by muse, mutect2, varscan2
- LAMB1 | c.1602C>A p.H534Q | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1203685024, COSV55967575; called by muse, mutect2, varscan2
- LAMB3 | c.1919G>C p.S640T | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61918166; called by muse, mutect2, varscan2
- LARP1 | c.1961G>T p.R654L (on ENST00000518297 / NM_033551.3; = p.R577L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60429174; called by muse, mutect2, varscan2
- LELP1 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV64202618; called by muse, mutect2, varscan2
- LGR6 | c.2809C>G p.L937V (on ENST00000367278 / NM_001017403.1; = p.L885V on NM_021636.3) | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV55161613; called by muse, mutect2, varscan2
- LHCGR | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54300270; called by muse, mutect2, varscan2
- LHFPL6 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV65447387; called by muse, mutect2, varscan2
- LILRA2 | c.1427G>T p.S476I (on ENST00000391738 / NM_001130917.3; = p.S459I on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV52194354; called by muse, mutect2, varscan2
- LMNB1 | c.1348G>C p.D450H | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54398858; called by muse, mutect2, varscan2
- LMNB2 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV57589452; called by muse, mutect2
- LRP1B | c.12622A>T p.N4208Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV67249356; called by muse, mutect2
- LRP1B | c.2770+2T>A p.X924_splice | Splice Site (SNP) | VAF 49/153 reads (32%) | catalogued as COSV63341858; called by muse, mutect2, varscan2
- LRP2 | c.12117G>A p.M4039I | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV55563270; called by muse, mutect2
- LRP2 | c.407G>C p.G136A | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV55563281; called by muse, mutect2
- LRRC10 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs771668401, COSV100825475; called by muse, mutect2, varscan2
- LRRC4C | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53432061; called by muse, mutect2, varscan2
- LRRC59 | c.82A>T p.N28Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs760087086, COSV56815075; called by mutect2, varscan2
- LRRC8A | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as COSV52187798; called by muse, mutect2
- LRRIQ1 | c.4997G>A p.G1666D | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1179478037, COSV67825586, COSV67834647; called by muse, mutect2, varscan2
- LRRTM4 | c.1288G>T p.V430L | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV69141042; called by muse, mutect2, varscan2
- LSAMP | c.93C>A p.S31R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); catalogued as rs1016458460, COSV61301906; called by muse, mutect2, varscan2
- LSS | c.2168A>T p.Y723F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.699); catalogued as COSV62701832; called by muse, mutect2, varscan2
- LTK | c.1784G>C p.G595A | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV53028579; called by muse, mutect2, varscan2
- LYST | c.4890G>T p.M1630I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV67710483; called by muse, mutect2, varscan2
- MAB21L1 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59803506; called by muse, mutect2, varscan2
- MACF1 | c.12296G>T p.S4099I (on ENST00000372915; = p.S2032I on NM_012090.5) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as rs1324543243, COSV57132375; called by muse, mutect2, varscan2
- MACO1 | c.1966G>C p.A656P | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65477373; called by muse, mutect2, varscan2
- MAGEC1 | c.2716T>A p.Y906N | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as COSV53577192; called by muse, mutect2, varscan2
- MANBA | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56968095; called by muse, mutect2, varscan2
- MAP2 | c.2024G>T p.S675I | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52299550; called by muse, mutect2, varscan2
- MAP4K1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 47/81 reads (58%) | catalogued as COSV67708703, COSV67711656; called by muse, mutect2, varscan2
- MAPRE2 | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55820294; called by muse, mutect2, varscan2
- MATN2 | c.2395G>C p.E799Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs1413517679, COSV54715431; called by muse, mutect2, varscan2
- MC2R | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV100562986; called by muse, mutect2, varscan2
- MCC | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as rs957272304, COSV56726946, COSV56732343; called by muse, mutect2, varscan2
- MCF2L | c.1319G>T p.C440F (on ENST00000375608; = p.C408F on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65052033; called by muse, mutect2, varscan2
- MCHR2 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56005779, COSV99912320; called by muse, mutect2, varscan2
- MCHR2 | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56005800; called by muse, mutect2, varscan2
- MDGA2 | c.1376A>T p.Q459L (on ENST00000399232 / NM_001113498.2; = p.Q161L on NM_182830.4) | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.71); catalogued as COSV100637134; called by muse, mutect2, varscan2
- METTL25 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV50260312; called by muse, mutect2
- MKKS | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1477287619, COSV61399293; called by muse, mutect2, varscan2
- MOCS2 | c.333G>T p.R111S | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100799026; called by muse, mutect2, varscan2
- MPDZ | c.3459A>T p.E1153D | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV59920898; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2040A>T p.E680D | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs753960251, COSV56622005; called by muse, mutect2, varscan2
- MROH2B | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV68186897; called by muse, mutect2, varscan2
- MROH2B | c.1815C>G p.Y605* | Nonsense Mutation (SNP) | VAF 63/296 reads (21%) | catalogued as COSV68186904; called by muse, mutect2, varscan2
- MROH7 | c.2308G>T p.V770F | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV59875111; called by muse, mutect2, varscan2
- MS4A14 | c.127A>T p.R43* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV55730892; called by muse, mutect2, varscan2
- MTMR1 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64892740; called by muse, mutect2, varscan2
- MTTP | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55503541, COSV55509361; called by muse, mutect2, varscan2
- MUC16 | c.28748C>A p.P9583H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.805); catalogued as COSV67479697; called by muse, mutect2, varscan2
- MUC16 | c.28373C>A p.S9458Y | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV67479698, COSV67495432; called by muse, mutect2, varscan2
- MUC16 | c.12273G>C p.M4091I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV67447314, COSV67479700; called by muse, mutect2, varscan2
- MUC17 | c.1526G>A p.G509E | Missense Mutation (SNP) | VAF 52/840 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV60295951; called by muse, mutect2
- MUC17 | c.4392C>A p.N1464K | Missense Mutation (SNP) | VAF 37/546 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60295958; called by muse, mutect2
- MUC17 | c.5087C>A p.T1696N | Missense Mutation (SNP) | VAF 126/419 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60295966; called by muse, mutect2, varscan2
- MUC17 | c.5803A>T p.T1935S | Missense Mutation (SNP) | VAF 32/518 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV60295975; called by muse, mutect2
- MUC17 | c.8519C>T p.P2840L | Missense Mutation (SNP) | VAF 136/656 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as COSV60295983; called by muse, varscan2
- MXRA5 | c.5735C>A p.T1912N | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54242731; called by muse, mutect2, varscan2
- MYCBPAP | c.1448-2A>T p.X483_splice | Splice Site (SNP) | VAF 29/89 reads (33%) | catalogued as COSV60409770; called by muse, mutect2, varscan2
- MYH2 | c.1425C>A p.S475R | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV55443184; called by muse, mutect2, varscan2
- MYH4 | c.4244G>T p.C1415F | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55122478; called by muse, mutect2, varscan2
- MYH6 | c.1849C>T p.L617F | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as rs1167547697, COSV62452712; called by muse, mutect2
- MYO3A | c.3134T>A p.V1045E | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56339638; called by muse, mutect2
- MYO7B | c.2165A>T p.Q722L | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV67349461; called by muse, mutect2, varscan2
- MYPN | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62736078; called by muse, mutect2, varscan2
- N4BP1 | c.2546G>T p.R849I | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52211939; called by muse, mutect2, varscan2
- NAA11 | c.439A>T p.M147L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV54515177; called by muse, mutect2, varscan2
- NAGLU | c.1577A>G p.N526S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56795577; called by muse, mutect2
- NALCN | c.4724G>T p.W1575L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51950321; called by muse, mutect2, varscan2
- NCALD | c.389A>G p.K130R | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV55273905; called by muse, mutect2, varscan2
- NCAPG | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV52271521; called by muse, mutect2, varscan2
- NCOA3 | c.4057G>T p.A1353S (on ENST00000371998 / NM_181659.3; = p.A1349S on NM_006534.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59070951; called by muse, mutect2, varscan2
- NCSTN | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.163); catalogued as rs906639053, COSV54189530; called by muse, mutect2, varscan2
- NDST4 | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as COSV52128449; called by muse, mutect2, varscan2
- NDST4 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV52128457; called by muse, mutect2, varscan2
- NELL1 | c.1538C>A p.T513N | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54278873, COSV54293523; called by muse, mutect2, varscan2
- NELL1 | c.1885T>C p.S629P | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as COSV54293533; called by muse, mutect2, varscan2
- NETO2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs555638989, COSV57452773, COSV57454155; called by muse, mutect2, varscan2
- NFATC3 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60476557; called by muse, mutect2, varscan2
- NFIC | c.54G>T p.E18D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59414461; called by muse, mutect2
- NKAPL | c.101G>C p.C34S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV100642504; called by muse, mutect2, varscan2
- NLGN1 | c.223G>T p.G75W | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765261134, COSV100848677, COSV64340835; called by muse, mutect2, varscan2
- NLRP12 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.404); catalogued as COSV60750759; called by muse, mutect2
- NLRP13 | c.596A>T p.K199I | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV61623094; called by muse, mutect2, varscan2
- NLRP3 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV60228473; called by muse, mutect2, varscan2
- NLRP4 | c.1810T>C p.F604L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs754572708, COSV56718647; called by muse, mutect2, varscan2
- NMNAT1 | c.276G>T p.W92C | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101020417; called by muse, mutect2, varscan2
- NOS1 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs561693400, COSV57612982, COSV57620960; called by muse, mutect2, varscan2
- NOTCH4 | c.5327G>A p.R1776Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs964712324, COSV66682443; called by muse, varscan2
- NOVA1 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.287); catalogued as COSV57473944; called by muse, mutect2, varscan2
- NPFFR2 | c.91C>A p.R31S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV58148317, COSV58151917; called by muse, mutect2, varscan2
- NPFFR2 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV58151924; called by muse, mutect2, varscan2
- NPLOC4 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58617747; called by muse, mutect2, varscan2
- NPSR1 | c.1057T>A p.F353I | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100706108, COSV62204592; called by muse, mutect2, varscan2
- NR1I3 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV63468727; called by muse, mutect2, varscan2
- NR4A3 | c.1448C>A p.S483Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58243704; called by muse, mutect2, varscan2
- NRG2 | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV56836721; called by muse, mutect2, varscan2
- NRG3 | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64573828; called by muse, mutect2, varscan2
- NRG3 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64573831, COSV64582310; called by muse, mutect2, varscan2
- NRXN1 | c.3500G>T p.R1167L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.632); catalogued as COSV58437320, COSV58472735; called by muse, mutect2, varscan2
- NT5C1A | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as COSV52495516; called by muse, mutect2, varscan2
- NTF3 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1354743162, COSV58417158, COSV58417973; called by muse, mutect2, varscan2
- NTM | c.308A>G p.Q103R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.156); catalogued as COSV66186318; called by muse, mutect2, varscan2
- NTNG1 | c.1296T>A p.C432* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV64275650; called by muse, mutect2, varscan2
- NUCKS1 | c.442A>C p.S148R | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV65653203; called by muse, mutect2, varscan2
- NUP214 | c.2732G>T p.S911I | Missense Mutation (SNP) | VAF 51/261 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV63911283; called by muse, mutect2, varscan2
- OBSCN | c.11068G>T p.D3690Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52800064; called by muse, mutect2, varscan2
- ODAM | c.528+2T>C p.X176_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as rs1295010510, COSV68573172; called by muse, mutect2, varscan2
- OLFM4 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV54577130; called by muse, mutect2
- OR10G8 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs368438499; called by muse, mutect2, varscan2
- OR10G8 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV70908952; called by muse, mutect2, varscan2
- OR13C5 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV66165011, COSV66165136; called by muse, mutect2, varscan2
- OR14A16 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV62927109; called by muse, mutect2, varscan2
- OR14A16 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV62927114; called by muse, mutect2, varscan2
- OR14K1 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV51721143, COSV99315167; called by muse, mutect2, varscan2
- OR2AK2 | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63557123, COSV63563546; called by muse, mutect2
- OR2M2 | c.967T>C p.F323L | Missense Mutation (SNP) | VAF 23/357 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV62898097; called by muse, mutect2
- OR2T4 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 32/327 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs779512657, COSV63544594; called by muse, mutect2
- OR2T4 | c.774C>G p.H258Q | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.312); catalogued as COSV63544583, COSV63544597; called by muse, mutect2, varscan2
- OR2T6 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs141134612; called by muse, mutect2, varscan2
- OR4D10 | c.682C>G p.Q228E | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV73260127; called by muse, mutect2, varscan2
- OR4D2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs751141957, COSV73459814; called by muse, mutect2, varscan2
- OR4K14 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV59293405; called by muse, mutect2, varscan2
- OR4K2 | c.800C>G p.T267R | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV53849706, COSV53850667; called by muse, mutect2, varscan2
- OR4L1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 73/199 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV59850594; called by muse, mutect2, varscan2
- OR51S1 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV59057956, COSV59059204; called by muse, mutect2, varscan2
- OR5AS1 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57982486; called by muse, mutect2, varscan2
- OR5B17 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV62160677; called by muse, mutect2, varscan2
- OR5F1 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.039); catalogued as COSV53547558; called by muse, varscan2
- OR5K1 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV60304808; called by muse, mutect2
- OR5K1 | c.629C>A p.T210N | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV60304815; called by muse, mutect2, varscan2
- OR5K4 | c.608C>A p.S203* | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV100721344; called by muse, mutect2, varscan2
- OR5L1 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV61734726, COSV61735495; called by muse, varscan2
- OR6B2 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53155548; called by muse, mutect2, varscan2
- OR7G1 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV53318263; called by muse, mutect2, varscan2
- OR8B3 | c.853A>T p.N285Y | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV63541960; called by muse, mutect2, varscan2
- OR8B8 | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs267602760, COSV60145155, COSV60145465; called by muse, mutect2, varscan2
- OR8H2 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV57946385; called by muse, mutect2, varscan2
- OR8H2 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV57946393; called by muse, mutect2
- OR8H3 | c.392A>T p.H131L | Missense Mutation (SNP) | VAF 65/262 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs760869816, COSV57910120; called by muse, mutect2, varscan2
- OR8J1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs759396550, COSV57319198, COSV57319258; called by muse, varscan2
- OR8J3 | c.824C>A p.S275Y | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56882691; called by muse, mutect2, varscan2
- OR8J3 | c.86T>A p.L29Q | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.707); catalogued as COSV56882706; called by muse, mutect2
- OR9I1 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56927024; called by muse, mutect2, varscan2
- OR9Q2 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.129); catalogued as COSV61111667, COSV61112303; called by muse, mutect2, varscan2
- OSGEP | c.557+1G>T p.X186_splice | Splice Site (SNP) | VAF 21/319 reads (7%) | catalogued as COSV52833174; called by muse, mutect2
- OTOGL | c.4322C>A p.A1441D (on ENST00000547103; = p.A1432D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV101509228; called by muse, mutect2, varscan2
- OXSM | c.475G>T p.V159F | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV55002127; called by muse, mutect2
- P2RY1 | c.330C>G p.Y110* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as COSV59309943; called by muse, mutect2, varscan2
- P2RY10 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV50682345, COSV50683308; called by muse, mutect2, varscan2
- P4HTM | c.1403C>A p.A468E (on ENST00000383729 / NM_177939.3; = p.A529E on NM_177938.2) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV59088177; called by muse, varscan2
- PADI2 | c.1660A>T p.I554F | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV64954263; called by muse, mutect2, varscan2
- PAK5 | c.250G>T p.G84C | Missense Mutation (SNP) | VAF 47/229 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV62032760, COSV62040191; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.557G>T p.G186V (on ENST00000374531 / NM_001037293.2; = p.G218V on NM_053016.6) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57126720; called by muse, mutect2, varscan2
- PAPPA2 | c.3564G>C p.L1188F | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); catalogued as COSV62804440; called by muse, mutect2, varscan2
- PAPPA2 | c.5141G>T p.C1714F | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62797375, COSV62804446; called by muse, mutect2
- PARM1 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0.341); catalogued as COSV100268052, COSV100268666; called by muse, mutect2
- PCDH1 | c.3167A>T p.H1056L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV54616890; called by muse, mutect2, varscan2
- PCDH11X | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53486671; called by muse, mutect2, varscan2
- PCDH15 | c.250T>A p.W84R | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs752604584, COSV57352670; called by muse, mutect2, varscan2
- PCDH17 | c.1336del p.D446Tfs*18 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as COSV64977771; called by mutect2, pindel, varscan2
- PCDH17 | c.2740G>A p.V914I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.42); catalogued as COSV100932086, COSV64976614; called by muse, mutect2, varscan2
- PCDH18 | c.2153T>C p.V718A | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.315); catalogued as rs143055456; called by muse, mutect2, varscan2
- PCDHB2 | c.1852G>T p.G618C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.25); catalogued as COSV99165098; called by muse, mutect2, varscan2
- PCDHGA7 | c.810C>A p.D270E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53912854, COSV53988586; called by muse, mutect2, varscan2
- PCDHGA7 | c.2178G>T p.Q726H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV53988596; called by muse, mutect2, varscan2
- PCDHGA8 | c.1383C>G p.I461M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs760903381, COSV53988605; called by muse, mutect2, varscan2
- PCDHGB7 | c.2314G>C p.D772H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.401); catalogued as COSV53988617; called by muse, mutect2, varscan2
- PCGF5 | c.434G>A p.C145Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV60238556, COSV60239918; called by muse, mutect2, varscan2
- PCK1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60129795; called by muse, mutect2, varscan2
- PCLO | c.4520G>A p.R1507K | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV100434784, COSV61650200; called by muse, mutect2
- PCNT | c.1077A>T p.E359D | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV64030694; called by muse, mutect2, varscan2
- PDE1C | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 73/395 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58502808; called by muse, mutect2, varscan2
- PDE8B | c.2548+1G>T p.X850_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | catalogued as COSV53741357; called by mutect2, varscan2
- PDGFA | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271034775, COSV63280108; called by muse, mutect2, varscan2
- PDGFD | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV56385858; called by muse, mutect2, varscan2
- PDHA2 | c.728G>T p.R243M | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54780494; called by muse, mutect2, varscan2
- PDZRN3 | c.2296A>T p.S766C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55208162; called by muse, mutect2, varscan2
- PES1 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 6/65 reads (9%) | catalogued as COSV58829215; called by muse, mutect2, varscan2
- PFKFB4 | c.1084A>G p.K362E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | PolyPhen benign (0.046); catalogued as COSV51681924; called by muse, mutect2
- PGLYRP3 | c.661C>A p.Q221K | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV51951519; called by muse, mutect2, varscan2
- PI4KA | c.2048G>T p.S683I | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV55416794; called by muse, mutect2, varscan2
- PIK3IP1 | c.70+1G>A p.X24_splice | Splice Site (SNP) | VAF 9/113 reads (8%) | catalogued as rs1289342858, COSV99314023; called by muse, mutect2
- PITX2 | c.8C>A p.T3N | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV61585636; called by muse, mutect2
- PKD1L1 | c.1757G>T p.R586M | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV56971736; called by muse, mutect2, varscan2
- PKD2 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.82); catalogued as rs775470869, COSV52939806; called by mutect2, varscan2
- PKDREJ | c.3517C>G p.R1173G | Missense Mutation (SNP) | VAF 59/254 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV53550947, COSV53552415; called by muse, mutect2, varscan2
- PKHD1L1 | c.3521C>T p.T1174I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV65747739; called by muse, mutect2, varscan2
- PKHD1L1 | c.9624G>C p.Q3208H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.254); catalogued as COSV65747742; called by muse, mutect2, varscan2
- PLA2G2A | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64287453; called by muse, mutect2, varscan2
- PLA2G3 | c.943C>G p.Q315E | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV53211057; called by muse, mutect2
- PLA2G4F | c.1985C>A p.P662Q | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs533703193, COSV51828272; called by muse, mutect2, varscan2
- PLA2R1 | c.4168C>G p.P1390A | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV51782671; called by muse, mutect2, varscan2
- PLOD2 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51466892; called by muse, mutect2, varscan2
- PLSCR4 | c.914A>T p.K305I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61608462; called by muse, mutect2, varscan2
- PODN | c.692A>G p.Y231C (on ENST00000395871; = p.Y183C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs1373840771, COSV57015316; called by muse, mutect2, varscan2
- POFUT2 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57957869, COSV57959518, COSV57960159, COSV57960382; called by muse, mutect2, varscan2
- POM121L12 | c.878C>A p.P293H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV68693534, COSV68694306; called by muse, mutect2, varscan2
- POP1 | c.2486G>A p.G829D | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV62893595; called by muse, mutect2, varscan2
- POSTN | c.1393G>T p.A465S | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV65713774; called by muse, mutect2, varscan2
- PPIP5K2 | c.281G>A p.C94Y | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58607657; called by muse, mutect2, varscan2
- PPM1G | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs150808424; called by muse, mutect2, varscan2
- PPP1R15A | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52339682; called by muse, mutect2, varscan2
- PPP1R15B | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV65816159; called by muse, mutect2
- PPP1R15B | c.1443C>G p.F481L | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV65816164; called by muse, mutect2
- PPP1R9A | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56901635; called by muse, mutect2, varscan2
- PRDM15 | c.2935G>T p.E979* | Nonsense Mutation (SNP) | VAF 19/185 reads (10%) | catalogued as COSV54156083; called by muse, mutect2, varscan2
- PRDM9 | c.1289C>A p.P430H | Missense Mutation (SNP) | VAF 49/176 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV57003080, COSV57009999; called by muse, mutect2, varscan2
- PRKCQ | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54115069; called by muse, mutect2, varscan2
- PRKD2 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52188288, COSV99354035; called by muse, mutect2, varscan2
- PRKN | c.1060G>C p.G354R | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV58210320, COSV58244936; called by muse, mutect2, varscan2
- PRKN | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV58244948; called by muse, mutect2, varscan2
- PROS1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 41/264 reads (16%) | catalogued as COSV101260460; called by muse, mutect2, varscan2
- PRPS1 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65054535, COSV65054656; called by muse, mutect2, varscan2
- PRSS16 | c.1351G>C p.V451L | Missense Mutation (SNP) | VAF 57/266 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.525); catalogued as COSV57916095; called by muse, mutect2, varscan2
- PRSS23 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99722380, COSV99722529; called by muse, mutect2, varscan2
- PRSS35 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63800923, COSV63801105; called by muse, mutect2, varscan2
- PRSS57 | c.139T>A p.Y47N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61386398; called by muse, mutect2
- PSD | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50050629; called by muse, mutect2, varscan2
- PSMC4 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50096500; called by muse, mutect2, varscan2
- PTGFR | c.100G>C p.V34L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV66115873; called by muse, mutect2, varscan2
- PTGR1 | c.68A>C p.E23A | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV53029992; called by muse, mutect2
- PTK2B | c.1640A>C p.H547P | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57761255; called by muse, mutect2, varscan2
- PTK7 | c.1884G>C p.K628N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100030494, COSV57850042; called by muse, mutect2, varscan2
- PTPRC | c.336C>G p.H112Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61416513; called by muse, mutect2
- PTPRG | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99874732; called by muse, mutect2
- PTPRG | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); catalogued as COSV99874735; called by muse, mutect2
- PTPRR | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.133); catalogued as COSV51739295; called by muse, mutect2, varscan2
- PTPRZ1 | c.283A>C p.I95L | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV66434580; called by muse, mutect2, varscan2
- PXDNL | c.4387C>A p.R1463S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV62491202, COSV62493452; called by mutect2, varscan2
- QSOX1 | c.1196A>G p.H399R | Missense Mutation (SNP) | VAF 74/204 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV62581069; called by muse, mutect2, varscan2
- RAB28 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as COSV56541002; called by muse, mutect2
- RAB2A | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV52911701, COSV52912721; called by muse, mutect2, varscan2
- RAB6C | c.542A>T p.Q181L | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV101308496; called by muse, varscan2
- RAB6C | c.597A>T p.Q199H | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV101308497; called by muse, varscan2
- RADIL | c.1078C>A p.Q360K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68202424; called by mutect2, varscan2
- RANGAP1 | c.1590G>T p.K530N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62364124; called by muse, mutect2, varscan2
- RAPGEF6 | c.1730A>T p.Q577L | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99726366; called by muse, mutect2, varscan2
- RBL1 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs770462344, COSV60331434; called by muse, mutect2, varscan2
- RBM19 | c.1978G>A p.G660S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV55695467; called by muse, mutect2, varscan2
- RBM24 | c.416C>A p.P139Q (on ENST00000379052 / NM_001143942.2; = p.P94Q on NM_153020.2) | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV59004360; called by muse, varscan2
- RBM48 | c.829A>G p.R277G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56003213; called by muse, mutect2, varscan2
- RELN | c.5041A>T p.S1681C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV59019469; called by muse, mutect2, varscan2
- RGS22 | c.3295G>C p.E1099Q | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV62664797; called by muse, mutect2, varscan2
- RHNO1 | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs909023254, COSV100817037; called by muse, mutect2, varscan2
- RIMS4 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.83); catalogued as COSV65719285, COSV65720221; called by muse, varscan2
- RIN1 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV60927765; called by muse, mutect2, varscan2
- RLIM | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60327865; called by muse, mutect2, varscan2
- RNF20 | c.2347G>C p.E783Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV66661761; called by muse, mutect2, varscan2
- RNF216 | c.2145A>T p.Q715H (on ENST00000425013 / NM_207116.3; = p.Q772H on NM_207111.4) | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV66291718; called by muse, mutect2, varscan2
- ROBO3 | c.1235C>A p.T412N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV67301751; called by muse, varscan2
- ROR2 | c.1167T>G p.C389W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65221649; called by muse, mutect2, varscan2
- RP1L1 | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101223083, COSV66757762; called by muse, mutect2, varscan2
- RPUSD4 | c.34T>A p.W12R | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.001); catalogued as COSV53599784, COSV53599959; called by muse, mutect2, varscan2
- RTCA | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53121512; called by muse, mutect2, varscan2
- RTTN | c.4593G>T p.R1531S | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.157); catalogued as COSV55345656; called by muse, mutect2, varscan2
- RXFP1 | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1455716936, COSV57053335; called by muse, mutect2, varscan2
- RYR2 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.542); catalogued as COSV63698950; called by muse, mutect2, varscan2
- RYR2 | c.3468G>T p.W1156C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV63698956; called by muse, mutect2, varscan2
- RYR2 | c.4990G>C p.V1664L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as COSV63698965, COSV63705585; called by muse, mutect2
- RYR2 | c.11888G>T p.S3963I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63698976; called by muse, mutect2, varscan2
- SACS | c.11296G>T p.V3766L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as rs200930332, COSV66543978; called by muse, mutect2, varscan2
- SAMD9 | c.1597A>T p.I533L | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV66076695; called by muse, mutect2
- SAMD9 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs148603551, COSV66072957, COSV66076701; called by muse, mutect2, varscan2
- SAP130 | c.236A>T p.H79L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.132); catalogued as COSV99384642; called by muse, mutect2, varscan2
- SCN10A | c.2738C>A p.A913D | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758836437, COSV71862234; called by muse, mutect2, varscan2
- SCN10A | c.2136G>T p.M712I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV71862235; called by muse, mutect2, varscan2
- SCN11A | c.5340C>G p.S1780R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); catalogued as COSV56574080; called by muse, mutect2, varscan2
- SCN11A | c.4852T>G p.L1618V | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56574087; called by muse, mutect2
- SCN11A | c.4850C>T p.P1617L | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56574093; called by muse, mutect2
- SCN2A | c.1435G>T p.G479W | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV51848583; called by muse, mutect2
- SCN4A | c.3222C>A p.Y1074* | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | catalogued as COSV71127870; called by muse, mutect2, varscan2
- SDHAF3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1401307855, COSV64491689; called by muse, mutect2, varscan2
- SDK1 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.654); catalogued as COSV67379763; called by muse, mutect2, varscan2
- SEC31A | c.3122C>T p.S1041L (on ENST00000355196 / NM_001318120.1; = p.S1002L on NM_016211.4) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV52348252; called by muse, mutect2
- SECISBP2L | c.2893G>A p.D965N (on ENST00000559471 / NM_001193489.2; = p.D920N on NM_014701.4) | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV55936131, COSV55937371; called by muse, mutect2, varscan2
- SEL1L3 | c.2494G>T p.G832C | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); catalogued as COSV53549488, COSV99340243; called by muse, mutect2, varscan2
- SEMA3D | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV99406560; called by muse, mutect2, varscan2
- SEMA3D | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52398659; called by muse, mutect2
- SEMA5A | c.2219C>A p.P740Q | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs199817743, COSV66799886; called by muse, mutect2, varscan2
- SERPINA11 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100593929, COSV58242575; called by muse, mutect2, varscan2
- SERPINB9 | c.100A>G p.S34G | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs368508487; called by muse, mutect2, varscan2
- SETX | c.2878A>T p.R960* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | catalogued as COSV56389746; called by muse, mutect2
- SEZ6L | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as COSV50671625; called by muse, mutect2, varscan2
- SGO2 | c.2710A>T p.N904Y | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV63416350; called by muse, mutect2
- SI | c.5057G>A p.R1686H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs191598487, COSV52283536; called by muse, mutect2, varscan2
- SIGLEC1 | c.3944C>A p.T1315K | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as COSV52468089; called by muse, mutect2, varscan2
- SIMC1 | c.2112G>C p.Q704H (on ENST00000443967 / NM_001308196.1; = p.Q289H on NM_198567.5) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV57905105; called by muse, mutect2, varscan2
- SIRPA | c.991T>A p.C331S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61540396; called by muse, mutect2
- SKA3 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100006334; called by muse, mutect2, varscan2
- SLC12A3 | c.2820G>C p.K940N (on ENST00000563236 / NM_001126108.2; = p.K949N on NM_000339.3) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as COSV52637023; called by muse, mutect2, varscan2
- SLC12A6 | c.1978G>T p.A660S (on ENST00000354181 / NM_001365088.1; = p.A609S on NM_005135.2) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV51628629; called by muse, mutect2, varscan2
- SLC13A4 | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62462012; called by muse, mutect2
- SLC15A4 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57162601; called by muse, mutect2
- SLC25A20 | c.116A>C p.Q39P | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59803915; called by muse, mutect2, varscan2
- SLC25A43 | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as COSV54218511; called by muse, mutect2, varscan2
- SLC26A3 | c.318G>T p.L106F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60638877; called by muse, mutect2, varscan2
- SLC36A1 | c.1057G>T p.V353F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54652308, COSV54655236; called by muse, mutect2, varscan2
- SLC39A12 | c.25G>T p.V9L | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV66200577; called by muse, mutect2, varscan2
- SLC3A2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV58604188; called by muse, mutect2, varscan2
- SLC7A14 | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV51586143; called by muse, mutect2, varscan2
- SLC8A1 | c.1714G>T p.V572F | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs151189284, COSV60488987; called by muse, mutect2, varscan2
- SLC8A1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60489014; called by muse, mutect2, varscan2
- SLC9A9 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV57236264; called by muse, mutect2, varscan2
- SLCO5A1 | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.056); catalogued as COSV52663653, COSV99479720; called by muse, mutect2, varscan2
- SLIT2 | c.2110G>A p.D704N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56583412; called by muse, mutect2, varscan2
- SLITRK1 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100999938; called by muse, mutect2, varscan2
- SLITRK4 | c.753G>C p.R251S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV62025179; called by muse, mutect2, varscan2
- SLITRK5 | c.1403G>T p.R468M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV61524518; called by muse, mutect2, varscan2
- SLITRK6 | c.2219C>A p.T740K | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs745310375, COSV68390922; called by muse, mutect2, varscan2
- SMAD3 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as COSV100528996; called by muse, mutect2
- SMARCA2 | c.3381A>T p.R1127S | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61810012; called by muse, mutect2, varscan2
- SMYD1 | c.1409C>A p.P470H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.743); catalogued as COSV70225568; called by muse, mutect2, varscan2
- SOBP | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57996818, COSV58000590; called by muse, mutect2, varscan2
- SORCS3 | c.2461C>T p.P821S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV63795163; called by muse, mutect2, varscan2
- SPRY2 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV101001684; called by muse, mutect2, varscan2
- SPRY2 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs947314080, COSV101001685; called by muse, mutect2, varscan2
- SPTA1 | c.813-1G>T p.X271_splice | Splice Site (SNP) | VAF 43/130 reads (33%) | catalogued as COSV63755307; called by muse, mutect2, varscan2
- SRCAP | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52676942; called by muse, mutect2, varscan2
- SRCAP | c.7139G>T p.R2380L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as rs761858529, COSV99350071; called by mutect2, varscan2
- SSH3 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV57385777; called by muse, mutect2, varscan2
- SSMEM1 | c.178G>T p.V60F | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV52833210, COSV52833914; called by muse, mutect2, varscan2
- SSTR4 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54799156; called by muse, mutect2
- ST8SIA6 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV66470090, COSV66472075; called by muse, mutect2, varscan2
- STXBP5L | c.2787G>T p.W929C | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as COSV56524058, COSV56534438; called by muse, mutect2, varscan2
- SULT4A1 | c.178T>A p.L60M | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.929); catalogued as COSV50782284; called by muse, varscan2
- SVEP1 | c.8848G>T p.G2950* | Nonsense Mutation (SNP) | VAF 41/275 reads (15%) | catalogued as COSV52841567; called by muse, mutect2, varscan2
- SVIL | c.3040G>A p.E1014K (on ENST00000355867 / NM_021738.3; = p.E588K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.26); catalogued as COSV63442938; called by muse, mutect2, varscan2
- SVOP | c.1110G>C p.E370D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV54467156; called by muse, mutect2, varscan2
- SYNE2 | c.17668C>T p.Q5890* | Nonsense Mutation (SNP) | VAF 16/174 reads (9%) | catalogued as COSV59959446; called by muse, mutect2
- SYNE3 | c.1682A>T p.Q561L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.169); catalogued as COSV62080824; called by muse, mutect2, varscan2
- TAB1 | c.1071C>A p.D357E | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV53372282; called by muse, mutect2
- TAF1L | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 63/222 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54265165, COSV54266904; called by muse, mutect2, varscan2
- TAFA5 | c.356G>T p.C119F (on ENST00000402357 / NM_001082967.3; = p.C112F on NM_015381.7) | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60968582; called by muse, mutect2, varscan2
- TARS2 | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64696297; called by muse, mutect2
- TAS1R1 | c.2068C>A p.Q690K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV59840244; called by muse, mutect2, varscan2
- TAS2R38 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71885328; called by muse, mutect2, varscan2
- TAS2R39 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs150355894, COSV71470988; called by muse, mutect2, varscan2
- TATDN2 | c.119A>T p.Q40L | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV55052919; called by muse, mutect2, varscan2
- TBX18 | c.1655G>T p.G552V | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV63737494, COSV63738579; called by muse, mutect2, varscan2
- TCEANC2 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV99328653; called by muse, mutect2, varscan2
- TCEANC2 | c.70G>T p.V24F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV99328654; called by muse, mutect2, varscan2
- TECPR2 | c.4120G>T p.G1374C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100849850, COSV63972176; called by muse, mutect2, varscan2
- TENM3 | c.601A>T p.T201S | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.973); catalogued as COSV69313959; called by muse, mutect2, varscan2
- TENT4A | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50097360, COSV50101151; called by muse, mutect2, varscan2
- TEX10 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1264002630, COSV66517191; called by muse, mutect2
- TEX47 | c.760T>A p.*254Kext*2 | Nonstop Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV51879576; called by muse, mutect2, varscan2
- TF | c.1147G>C p.G383R | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV53922006; called by muse, mutect2, varscan2
- TFIP11 | c.363+1G>A p.X121_splice | Splice Site (SNP) | VAF 17/104 reads (16%) | catalogued as COSV68021074; called by muse, mutect2, varscan2
- TG | c.486G>C p.R162S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.175); catalogued as COSV55080469, COSV55086005; called by muse, mutect2, varscan2
- TGDS | c.314-1G>C p.X105_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | catalogued as COSV54301694; called by muse, mutect2
406 further variants in this file (121 protein-altering or splice-affecting, 256 silent, 29 other) are not listed here.
